Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0YC, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0YC-01A (Primary Tumor).

[page 1 of 3]
ICA-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 1/27/11

SURGICAL REPORT

Name:

Sex: F

DOB:

Location:

Doctor:

Pathology Number

Date Collected:

Date Received:

M.R. Number:

Account Number:

**** THIS IS A CORRECTED REPORT ****
******* CORRECTED REPORT *******

PRE-OPERATIVE DIAGNOSIS

RIGHT BREAST CANCER

POST-OPERATIVE DIAGNOSIS

RIGHT BREAST CANCER

PROCEDURE

EXCISION BIOPSY RIGHT BREAST LUMPECTOMY WITH SENTINEL LYMPH NODE BIOPSY (F.S.)

TISSUES

- A. LYMPH NODE (S) - RIGHT SENTINEL LYMPH NODE #1 **FS**
- B. LYMPH NODE (S) - RIGHT SENTINEL LYMPH NODE #2 **FS**
- C. LYMPH NODE (S) - ADDITIONAL NODE NON SENTINEL **FS**
- D. BREAST EXCISION, NEEDLE LOC, SIMPLE, MARGINS, ETC. - RIGHT BREAST LUMPECTOMY
- WRI TISSUE

ADDENDUM

Immunostain for Cytokeratin was performed on specimens "A", "B", "C" and is negative for metastatic adenocarcinoma.

Reviewed and electronically signed out by:
Pathologist

FS DIAGNOSIS

- A. RIGHT SENTINEL LYMPH NODE #1, F.S. -
NEGATIVE LYMPH NODE (2 BLOCKS).
- B. RIGHT SENTINEL LYMPH NODE #2, F.S. -
NEGATIVE LYMPH NODE.
- C. NON-SENTINEL NODE, F.S. -
NEGATIVE LYMPH NODE.
- D. RIGHT BREAST (GROSS MARGINS) -
MARGINS ARE FREE (GROSS).

(Reported to Surgeon: _____)

Patient Na _____

F

SURGICAL REPORT

[page 2 of 3]
Patient Name

Pathology Number:

Diagnosed by:

FINAL DIAGNOSIS

- A. **RIGHT SENTINEL LYMPH NODE #1 -
ONE POSITIVE LYMPH NODE (1/1, MICROSCOPIC METASTATIC DUCTAL
CARCINOMA, 1 MM IN MAXIMAL DIMENSION. PLEASE SEE COMMENT).**
- B. **RIGHT SENTINEL LYMPH NODE #2 -
ONE NEGATIVE LYMPH NODE (0/1).**
- C. **NON-SENTINEL LYMPH NODE -
ONE NEGATIVE LYMPH NODE (0/1).**
- D. **RIGHT BREAST LUMPECTOMY -
MODERATELY DIFFERENTIATED INFILTRATING DUCTAL CARCINOMA.
SCARFF-BLOOM-RICHARDSON GRADE II/III.
THE TUMOR MEASURES 2.5 CM. IN MAXIMUM DIMENSION.
ALL SURGICAL MARGINS ARE FREE OF THE LESION. THE CLOSEST SURGICAL
MARGINS ARE THE DEEP (POSTERIOR) SURGICAL MARGIN WHICH IS 1 MM. FROM
TUMOR (SLIDE 6) AND THE INFERIOR MARGIN, WHICH IS 4MM FROM THE INFERIOR
MARGIN (SLIDE 4) .**

TUMOR STAGE: STAGE IIB, T2, N1mic, MX (GRADE 2).

Diagnosed by:

Reviewed and electronically signed out by:

COMMENT

Specimen "A" shows microscopic metastatic carcinoma which is only present in the permanent section and not in the frozen section. This case is discussed with _____ on _____ by _____

COMMENT2

This case is amended at the request of _____ to correct the tumor stage from T2, N1, MX to T2, N1mic, MX

GROSS DESCRIPTION

- The specimen is received in four separate containers labeled _____ designated A, B, C, D.
- A. The container is received fresh unfixed labeled "right sentinel lymph node #1 for frozen section". The specimen consists of an ovoid nodule of tan-gray firm rubbery tissue which is 1.5 x 1 x 0.4 cm. and has attached fatty material. A single node is bisected and entirely submitted as two frozen sections by Dr. _____. The entire specimen including frozen sections are submitted in three blocks.
- B. The container is received fresh unfixed labeled "right sentinel lymph node #2 for frozen section". The specimen consists of an ovoid nodule of firm tan-gray soft rubbery tissue and attached fat

Patient Name:

Pathology Number:

SURGICAL REPORT

Page 2 of 3

[page 3 of 3]
Patient Name

Pathology Number

and measures 1 x 0.3 x 0.3 cm. The node is bisected and entirely submitted as a frozen section by Dr. The entire specimen including frozen section is submitted in two blocks.

- C. The container is received fresh unfixed labeled "additional node non-sentinel for frozen section". The specimen consists of an ovoid nodule of pink-tan firm rubbery tissue with a scant amount of attached fat 0.6 x 0.4 x 0.3 cm. in greatest dimension. The entire specimen is submitted as a frozen section by Dr. The entire specimen is submitted in one block.
- D. The container is received fresh unfixed labeled "right breast lump" and consists of a 41 gm. ovoid mass of apparent fatty tissue with an attached skin ellipse 5.5 x 4.5 x 3.5 cm. in greatest overall dimension. The attached skin ellipse is 4 x 1 cm. in greatest overall dimension. Gross margins are observed and appear free by Dr. There is a long suture indicating lateral margin inked with purple dye, medial is inked red. There is a single short suture indicating superior margin inked with orange dye, inferior is inked black. The skin is designated as anterior, posterior is inked yellow. Sectioning reveals a firm tan-gray striated mass which is 2.5 x 2 cm. in greatest overall dimension and grossly appears to be 0.4 cm. away from the inferior margin, 0.8 cm. away from the superior margin, 0.3 cm. away from the posterior, 0.8 cm. away from the medial margin and 1 cm. away from the inferior. The specimen is submitted in eleven blocks.

Key Note Block Summary: 1—lateral, 2—medial, 3—superior, 4—inferior, 5—anterior, 6—posterior, 7 through 10—tumor, 11—skin.

MICROSCOPIC EXAM

MICROSCOPIC EXAMINATION CONDUCTED BY PATHOLOGIST CONFIRMS FINAL DIAGNOSIS.

SPECIAL STAINS PERFORMED: Cytokeratin (AE1/AE3) (specimens A, B, C) (LQ)

Patient Name:

Pathology Number:

SURGICAL REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file 064f5bba-44e9-4ea0-a829-87c31dd2fdd1 (TCGA-A2-A0YC.9BAD4BD4-A54B-4115-A00E-6AA88F344FE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).